Surgical pathology report (de-identified scan), TCGA case TCGA-P4-A5E8, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site  MD Anderson Cancer Center, specimen TCGA-P4-A5E8-01A (Primary Tumor).

[page 1 of 2]
Department of Pathology

Tissue Source Site (TSS) #:

Pathology Accession No:

Patient ID:

Normal Sample ID:

Pathology Report

DIAGNOSIS

(A) LEFT KIDNEY WITH REGIONAL LYMPH NODES:
PAPILLARY RENAL CELL CARCINOMA (10.0 CM MAXIMUM DIMENSION), FUHRMAN
NUCLEAR GRADE 3,
WITH VASCULAR-LYMPHATIC INVASION, CONFINED TO THE KIDNEY. (SEE COMMENT)

Margins of resection free of tumor.

Adrenal gland, no tumor present.

METASTATIC PAPILLARY RENAL CELL CARCINOMA IN THREE OF THREE LYMPH
NODES.

(B) PARA-AORTIC LYMPH NODES:

METASTATIC PAPILLARY RENAL CELL CARCINOMA IN MATTED LYMPH NODES.

(SEE COMMENT)

ICD-O-3

Carcinoma, papillary
renal cell 8260/3

Site: Kidney NOS
264.9

9/11/13

COMMENT

The papillary renal cell carcinoma is composed of papillae lined by tall columnar cells. Most tumor cells have eosinophilic cytoplasm, and some cells have clear cytoplasm. These morphologic features are consistent with type 2 papillary renal cell carcinoma. The tumor appears to be confined to the kidney and does not show invasion into the renal sinus adipose tissue, perinephric fat or the renal vein.

The para-aortic lymph nodes (specimen B) involved by metastatic renal cell carcinoma are matted together, hence the exact number of lymph nodes cannot be assessed. In addition to tumor in the lymph nodes there are small foci of tumor within vascular-lymphatic spaces in the perinodal adipose tissue.

GROSS DESCRIPTION

(A) LEFT KIDNEY WITH REGIONAL LYMPH NODE, VACCINE PROTOCOL - A radical nephrectomy specimen (21.0 x 15.0 x 8.5 cm) including the left kidney (12.5 x 11.0 x 7.3 cm), a segment of renal artery, the renal vein and ureter (1.4 cm in length and 0.5 cm average diameter) and the adrenal gland (5.5 x 2.0 x 1.4 cm).

There is a 10.0 x 8.5 x 8.5 cm well circumscribed tumor in the lower/mid pole of the kidney. The tumor is tan-gray and friable with focal areas of hemorrhage and necrosis throughout. The tumor is well circumscribed and does not grossly invade into perinephric adipose tissue, renal sinus, or renal vein. The tumor does not extend to Gerota's fascia. Three enlarged lymph nodes (0.6 to 2.9 cm in greatest dimension) are identified in the hilum of the kidney. These are grossly involved by tumor. The adjacent kidney parenchyma is unremarkable. The pelvicalyceal system is smooth and devoid of any lesions. Serial cross sections of the left adrenal gland show unremarkable cortex and medulla.

Tumor has been submitted for the vaccine protocol. Portions of the tumor have also been submitted for possible electron microscopy. Photographs were obtained.

INK CODE: Blue - Gerota's fascia.

SECTION CODE: A1, renal vein, renal artery, and ureter margins; A2, adrenal gland, representative sections; A3, tumor with nearest soft tissue margin; A4-A6, tumor and adjacent uninvolved kidney; A7, A8, tumor and renal sinus; A9-A12, representative sections of tumor; A13, one hilar lymph node, representative section; A14, one hilar lymph node, representative section; A15, one hilar lymph node bisected.

(B) PARA-AORTIC LYMPH NODE - Three irregular fragments of soft tissue (8.0 x 5.0 x 3.0 cm in aggregate). On cut surface it appears to be a matted aggregate of variegated white-yellow-red tumor. No residual lymph node tissue is grossly identified.

Representative sections
submitted in B1-B5.

CLINICAL HISTORY

None given.

SNOMED CODES

T-71000, M-83123, M-Y1593, T-C4400, M-83126, M-Y1596

[page 2 of 2]
Department of Pathology

Tissue Source Site (TSS) #:

Patholgy Accession No:

Patient ID:

Normal Sample ID:

Tumor Sample ID:

"Some tests reported here may have been developed and performance characteristics determined by

These tests have not been specifically cleared or approved by the U.S. Food and Drug Administration."

Source: NCI Genomic Data Commons file c00bace6-4131-437b-93ce-05288402f44e (TCGA-P4-A5E8.E62609FC-BB2B-482F-A3C8-902B27682D19.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).